Somatic mutation profile of tumor specimen TARGET-20-PASUHK-04A (aliquot TARGET-20-PASUHK-04A-01D) from TARGET case TARGET-20-PASUHK, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (549 days).
Specimen TARGET-20-PASUHK-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55dddec4-978f-467f-8412-6acac8bb716d.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASUHK-14A (Bone Marrow Normal), aliquot TARGET-20-PASUHK-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d1e60ca-26c4-469b-b8ec-152aeab7c0cf

The open-access MAF lists 8 somatic variants for this specimen: 1 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 6, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRC | c.3222G>A p.Q1074= | Silent (SNP) | VAF 71/222 reads (32%) | catalogued as rs190241405; called by muse, mutect2, varscan2
- CTNNB1 | c.*773_*787delinsAATTCATAATCACTC | 3'UTR (ONP) | VAF 54/96 reads (56%) | called by pindel, varscan2*
- GATA2 | c.*1146A>G | 3'UTR (SNP) | VAF 40/100 reads (40%) | catalogued as rs776209943; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDAC9 | c.*386_*387del | 3'UTR (DEL) | VAF 135/417 reads (32%) | catalogued as rs1474154295; called by mutect2, pindel, varscan2
- LPP | c.*4633A>G | 3'UTR (SNP) | VAF 96/264 reads (36%) | catalogued as rs757099306; called by muse, mutect2, varscan2
- NFATC2 | c.*2957A>T | 3'UTR (SNP) | VAF 98/266 reads (37%) | catalogued as rs572363666; called by muse, mutect2, varscan2
- PTGS2 | c.-34C>G | 5'UTR (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- TRPS1 | c.*925A>G | 3'UTR (SNP) | VAF 126/304 reads (41%) | catalogued as rs943462282; called by muse, mutect2, varscan2
